Somatic mutation profile of cancer-model specimen HCM-BROD-0831-C71-85B (Adherent Cell Line, passage 10; aliquot HCM-BROD-0831-C71-85B-01D-A85K-36), derived from the primary tumor of HCMI case HCM-BROD-0831-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.1 years (28,542 days).
Specimen HCM-BROD-0831-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3c3286c-7e91-4801-af5b-6ba48183ae15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0831-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0831-C71-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dff288d4-6fea-4a41-a9d1-127230428f9d

The open-access MAF lists 105 somatic variants for this specimen: 67 protein-altering or splice-affecting, 33 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 33, Intron 3, Nonsense Mutation 2, 3'UTR 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.7982C>T p.S2661L | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs746854104; called by muse, varscan2
- APOB | c.11809G>A p.E3937K | Missense Mutation (SNP) | VAF 108/220 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs766656064, COSV51925162; called by muse, mutect2, varscan2
- BRCC3 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs782796649; called by muse, mutect2, varscan2
- BRDT | c.2530G>T p.E844* | Nonsense Mutation (SNP) | VAF 147/297 reads (49%) | catalogued as COSV62863840; called by muse, mutect2, varscan2
- CDH6 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 128/257 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs764565018, COSV54078937; called by muse, mutect2, varscan2
- CDS2 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 177/343 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs904904787; called by muse, mutect2, varscan2
- CPS1 | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 137/313 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as rs779382562; called by muse, mutect2, varscan2
- CRNN | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 140/318 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs201339909; called by muse, mutect2, varscan2
- FANCD2 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 137/295 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs144332316; called by muse, mutect2, varscan2
- FLT4 | c.2431G>C p.G811R | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56121969; called by muse, mutect2, varscan2
- GORASP2 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434726317, COSV52204086; called by muse, mutect2, varscan2
- IGSF10 | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 140/314 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs372539492; called by muse, mutect2, varscan2
- IRS1 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 192/384 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs201965582; called by muse, mutect2, varscan2
- KIAA1958 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 164/339 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV61722697; called by muse, mutect2, varscan2
- KIAA2012 | c.3287G>A p.R1096Q | Missense Mutation (SNP) | VAF 152/307 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.464); catalogued as rs749854414; called by muse, mutect2, varscan2
- KSR2 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 159/340 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.608); catalogued as rs779973325, COSV56673180; called by muse, mutect2, varscan2
- MAP7D3 | c.698C>G p.S233W | Missense Mutation (SNP) | VAF 177/317 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60171013; called by muse, mutect2, varscan2
- MRGPRX4 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 85/168 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758613833, COSV100049711; called by muse, mutect2, varscan2
- MROH2B | c.3043G>A p.G1015S | Missense Mutation (SNP) | VAF 182/344 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.144); catalogued as rs1211364496, COSV68181233, COSV68191170; called by muse, mutect2, varscan2
- MUC2 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 146/276 reads (53%) | SIFT tolerated (0.46); catalogued as rs751277029; called by muse, varscan2
- NCR3LG1 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); catalogued as COSV100164430; called by muse, mutect2, varscan2
- NEDD4 | c.2120C>T p.S707L (on ENST00000508342 / NM_001284338.1; = p.S288L on NM_006154.4) | Missense Mutation (SNP) | VAF 17/401 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1223767842; called by muse, mutect2
- NIBAN1 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 84/161 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1429868422; called by muse, mutect2, varscan2
- OR2G2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 172/372 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs760919741, COSV60739255; called by muse, mutect2
- OR52E2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 161/313 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58612873; called by muse, mutect2, varscan2
- PCDHA13 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 266/501 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as rs144119560, COSV56499067; called by muse, mutect2, varscan2
- PCLO | c.15201A>T p.K5067N | Missense Mutation (SNP) | VAF 150/486 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61664320; called by muse, mutect2, varscan2
- PFKFB1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 156/282 reads (55%) | PolyPhen probably damaging (0.917); catalogued as COSV66628219; called by muse, mutect2, varscan2
- PIGT | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 109/200 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV99648938, COSV99649101; called by muse, mutect2, varscan2
- PLPPR4 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100926975; called by muse, mutect2, varscan2
- SEC16A | c.3271G>A p.G1091R | Missense Mutation (SNP) | VAF 197/419 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs1192420124; called by muse, mutect2, varscan2
- SETD1A | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 225/465 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs774783241; called by muse, mutect2, varscan2
- TAF4B | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs536777986, COSV52310932; called by muse, mutect2, varscan2
- TTN | c.12119T>C p.I4040T (on ENST00000591111; = p.I3994T on NM_003319.4) | Missense Mutation (SNP) | VAF 174/357 reads (49%) | catalogued as rs770591157; called by muse, mutect2, varscan2
- ZMAT4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs776568390, COSV52690119; called by muse, mutect2, varscan2
- ZNF98 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 30/395 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100757427, COSV99078222; called by muse, mutect2
- ADAMTS19 | c.3389A>G p.N1130S | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ATP2B2 | c.1118C>A p.S373Y (on ENST00000352432; = p.S339Y on NM_001683.5) | Missense Mutation (SNP) | VAF 247/460 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCP110 | c.2499C>G p.F833L | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CLIP2 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 191/620 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DENND2A | c.2369A>G p.Y790C | Missense Mutation (SNP) | VAF 162/527 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GK2 | c.439A>C p.T147P | Missense Mutation (SNP) | VAF 162/355 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- HS6ST2 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 282/573 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- IGFN1 | c.841A>G p.R281G | Missense Mutation (SNP) | VAF 184/366 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO5 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 151/298 reads (51%) | called by muse, mutect2, varscan2
- KRT77 | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 310/601 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LLCFC1 | c.204G>C p.Q68H (on ENST00000458732; = p.Q37H on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/528 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- MRPS5 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NCOA6 | c.212dup p.N71Kfs*60 | Frame Shift Ins (INS) | VAF 79/207 reads (38%) | called by mutect2, pindel, varscan2
- NF2 | c.1501A>T p.I501F | Missense Mutation (SNP) | VAF 155/155 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NWD1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 210/442 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- PCDH7 | c.1919T>G p.M640R | Missense Mutation (SNP) | VAF 182/333 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- POLG | c.893A>C p.H298P | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP5C | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 127/291 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- PRKAG1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 143/308 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RALGAPA1 | c.3775C>T p.P1259S | Missense Mutation (SNP) | VAF 116/120 reads (97%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCT | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 147/288 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- SLC4A1AP | c.914A>T p.K305M | Missense Mutation (SNP) | VAF 176/383 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SMG6 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 182/378 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TTN | c.65642A>T p.E21881V (on ENST00000591111; = p.E14457V on NM_003319.4) | Missense Mutation (SNP) | VAF 167/361 reads (46%) | PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TXNRD3 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 175/324 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- UPF3B | c.1322T>A p.L441H (on ENST00000276201 / NM_080632.3; = p.L428H on NM_023010.3) | Missense Mutation (SNP) | VAF 164/343 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VPS13D | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 165/334 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIRP2 | c.5870A>G p.D1957G (on ENST00000628543; = p.D2132G on NM_152381.6) | Missense Mutation (SNP) | VAF 141/265 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE26 | c.4674+1G>A p.X1558_splice | Splice Site (SNP) | VAF 79/79 reads (100%) | called by muse, mutect2, varscan2
- ZNF462 | c.7147G>A p.E2383K | Missense Mutation (SNP) | VAF 137/137 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, varscan2
- ZNF735 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 127/417 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ADGRL3 | c.4719G>A p.P1573= (on ENST00000506720 / NM_001322402.2; = p.P1462= on NM_015236.6) | Silent (SNP) | VAF 91/206 reads (44%) | catalogued as rs771284076, COSV72229236; called by muse, mutect2, varscan2
- ALK | c.2265C>T p.H755= | Silent (SNP) | VAF 193/350 reads (55%) | catalogued as rs770603023, COSV66565155; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMDHD1 | c.891G>A p.T297= | Silent (SNP) | VAF 132/278 reads (47%) | catalogued as rs547323409; called by muse, mutect2, varscan2
- AMOT | c.1725A>C p.R575= (on ENST00000371959 / NM_001113490.1; = p.R166= on NM_133265.3) | Silent (SNP) | VAF 197/420 reads (47%) | called by muse, mutect2, varscan2
- CRISP3 | c.75C>A p.T25= (on ENST00000371159 / NM_001368123.1; = p.T17= on NM_001190986.2) | Silent (SNP) | VAF 213/406 reads (52%) | catalogued as COSV53823148; called by muse, mutect2, varscan2
- CTAGE1 | c.303C>T p.C101= | Silent (SNP) | VAF 198/405 reads (49%) | catalogued as rs1474288797, COSV66942850; called by muse, mutect2, varscan2
- DDX27 | c.1932G>A p.V644= | Silent (SNP) | VAF 155/358 reads (43%) | called by muse, mutect2, varscan2
- DENND1C | c.507C>T p.S169= | Silent (SNP) | VAF 178/354 reads (50%) | called by muse, mutect2, varscan2
- DNAH7 | c.10407C>T p.P3469= | Silent (SNP) | VAF 154/364 reads (42%) | called by muse, varscan2
- DRP2 | c.2553G>A p.T851= | Silent (SNP) | VAF 273/553 reads (49%) | catalogued as rs1203536460; called by muse, mutect2, varscan2
- EXOC3L1 | c.99G>A p.A33= | Silent (SNP) | VAF 204/404 reads (50%) | catalogued as rs146322735; called by muse, mutect2, varscan2
- FAM47B | c.1752C>T p.D584= | Silent (SNP) | VAF 227/488 reads (47%) | catalogued as COSV61452643; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1890G>A p.E630= | Silent (SNP) | VAF 145/422 reads (34%) | called by muse, mutect2, varscan2
- GRM3 | c.810C>G p.R270= | Silent (SNP) | VAF 233/715 reads (33%) | catalogued as COSV64480463, COSV64480794; called by muse, mutect2, varscan2
- GSG1L2 | c.585T>C p.D195= | Silent (SNP) | VAF 122/279 reads (44%) | catalogued as rs1318006194; called by muse, mutect2, varscan2
- H4-16 | c.168G>A p.R56= | Silent (SNP) | VAF 195/412 reads (47%) | called by muse, mutect2, varscan2
- KCNJ3 | c.213C>A p.L71= | Silent (SNP) | VAF 178/362 reads (49%) | catalogued as COSV54543707; called by mutect2, varscan2
- KLF14 | c.18G>A p.A6= | Silent (SNP) | VAF 128/387 reads (33%) | called by muse, mutect2, varscan2
- LCN15 | c.36G>A p.L12= | Silent (SNP) | VAF 180/344 reads (52%) | called by muse, mutect2, varscan2
- LILRB5 | c.57C>T p.T19= | Silent (SNP) | VAF 180/412 reads (44%) | catalogued as COSV60257064; called by muse, varscan2
- LRP2 | c.381C>T p.C127= | Silent (SNP) | VAF 150/300 reads (50%) | called by muse, mutect2, varscan2
- MARCHF4 | c.858G>T p.V286= | Silent (SNP) | VAF 91/227 reads (40%) | called by muse, mutect2, varscan2
- OR2T8 | c.837C>T p.F279= | Silent (SNP) | VAF 100/193 reads (52%) | catalogued as COSV100178020; called by muse, mutect2, varscan2
- PPEF1 | c.438C>G p.T146= | Silent (SNP) | VAF 103/250 reads (41%) | called by muse, mutect2, varscan2
- PRR23A | c.654G>A p.P218= | Silent (SNP) | VAF 183/354 reads (52%) | catalogued as rs1217185242; called by muse, mutect2, varscan2
- PTPN3 | c.2277A>T p.P759= | Silent (SNP) | VAF 134/302 reads (44%) | called by muse, mutect2, varscan2
- ROS1 | c.1077G>A p.L359= | Silent (SNP) | VAF 117/273 reads (43%) | called by muse, mutect2, varscan2
- SEMA7A | c.1827C>A p.G609= | Silent (SNP) | VAF 223/461 reads (48%) | catalogued as COSV56089705; called by muse, mutect2, varscan2
- SPEF1 | c.696G>A p.E232= | Silent (SNP) | VAF 109/245 reads (44%) | called by muse, mutect2, varscan2
- SPTA1 | c.6273C>T p.S2091= | Silent (SNP) | VAF 199/423 reads (47%) | catalogued as COSV63750195; called by muse, mutect2, varscan2
- TPCN2 | c.330C>T p.D110= | Silent (SNP) | VAF 268/498 reads (54%) | catalogued as rs199768477, COSV53733691; called by muse, mutect2, varscan2
- TRHDE | c.12C>T p.D4= | Silent (SNP) | VAF 190/389 reads (49%) | catalogued as COSV99671752; called by muse, mutect2, varscan2
- TRPC7 | c.2526C>T p.S842= | Silent (SNP) | VAF 168/353 reads (48%) | catalogued as rs371371913; called by muse, mutect2, varscan2
- HS6ST2 | c.948-40039A>C | Intron (SNP) | VAF 151/330 reads (46%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-18116C>T | Intron (SNP) | VAF 126/265 reads (48%) | catalogued as rs770361058; called by muse, mutect2, varscan2
- PEG10 | c.*589A>G | 3'UTR (SNP) | VAF 113/421 reads (27%) | called by muse, mutect2, varscan2
- TBXA2R | c.*718G>C | 3'UTR (SNP) | VAF 75/147 reads (51%) | called by muse, mutect2, varscan2
- TTN | c.33340+384G>A | Intron (SNP) | VAF 80/189 reads (42%) | catalogued as rs894171947, COSV60086368; called by muse, mutect2, varscan2
